Somatic mutation profile of tumor specimen MMRF_1100_1_BM_CD138pos (aliquot MMRF_1100_1_BM_CD138pos_T2_TSE61_K03421) from MMRF case MMRF_1100, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,071 days).
Specimen MMRF_1100_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db7714d1-bab7-4ec5-b169-0702e67972b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1100_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1100_1_PB_Whole_C1_TSE61_K03423; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba306f7b-10e3-401d-910d-8f7d97e0ff87

The open-access MAF lists 89 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 23, Silent 17, 3'Flank 4, 5'UTR 3, Frame Shift Del 2, Nonsense Mutation 2, Intron 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AICDA | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as rs763170620, COSV57563730; called by muse, mutect2, varscan2
- ANKRD34C | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.396); catalogued as rs569161480; called by muse, mutect2, varscan2
- ASPM | c.4496G>A p.R1499Q | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140119882; called by muse, mutect2, varscan2
- COL7A1 | c.4847G>C p.G1616A | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60394199; called by muse, mutect2, varscan2
- MYH2 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs150705907, COSV55433291; called by muse, mutect2, varscan2
- RERE | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767855706, COSV100556747; called by muse, mutect2, varscan2
- SOX17 | c.1078C>A p.R360S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1437921769, COSV52028135; called by muse, mutect2, varscan2
- TMEM132D | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); catalogued as rs774737688; called by muse, mutect2, varscan2
- TTN | c.48992G>A p.R16331Q (on ENST00000591111; = p.R8907Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/30 reads (53%) | PolyPhen possibly damaging (0.535); catalogued as rs377169251, COSV100615105; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC45B | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs529858933, COSV52093267, COSV52101965; called by muse, mutect2, varscan2
- CHDH | c.1250A>C p.Q417P | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CNDP2 | c.829T>A p.Y277N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNST | c.1582_1592del p.M528Gfs*5 | Frame Shift Del (DEL) | VAF 52/114 reads (46%) | called by mutect2, pindel, varscan2
- DSTYK | c.2522T>G p.I841S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- EXO5 | c.250A>G p.T84A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- FBRSL1 | c.3052C>T p.R1018W | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- GC | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HBA1 | c.406G>C p.V136L | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IP6K2 | c.1012A>G p.K338E | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ITPKB | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNC2 | c.857_859del p.E286del | In Frame Del (DEL) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- LRRC8C | c.364T>G p.W122G | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- LRRIQ1 | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- MEGF8 | c.1904T>C p.V635A | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MGAM2 | c.4116G>T p.L1372F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MKRN3 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- MYH11 | c.3963+1G>A p.X1321_splice | Splice Site (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- MYH2 | c.5294T>C p.I1765T | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, varscan2
- NEK11 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- OLIG2 | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, mutect2
- PDE6B | c.1085C>G p.A362G | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- PKHD1L1 | c.5339C>T p.A1780V | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRAMEF11 | c.625A>G p.I209V | Missense Mutation (SNP) | VAF 108/237 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PRPF40A | c.1446A>T p.K482N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PRPF40A | c.1444A>T p.K482* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2
- SCGB2B2 | c.49A>T p.S17C | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); called by muse, mutect2
- SH3RF1 | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TNFRSF10A | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2
- TTN | c.47154del p.A15719Lfs*8 (on ENST00000591111; = p.A8295Lfs*8 on NM_003319.4) | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- ZNF136 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AGAP2 | c.1233G>A p.V411= (on ENST00000547588 / NM_001122772.2; = p.V75= on NM_014770.4) | Silent (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- CCND1 | c.501A>G p.K167= | Silent (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- CDC14C | c.306G>T p.S102= | Silent (SNP) | VAF 118/224 reads (53%) | catalogued as rs574526908; called by muse, mutect2, varscan2
- CIDEA | c.393C>T p.F131= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs758893653, COSV57599580; called by muse, mutect2, varscan2
- FAM167B | c.21A>G p.K7= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- FLG2 | c.3516C>T p.G1172= | Silent (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- GFPT2 | c.1743G>A p.L581= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs200888012; called by muse, mutect2, varscan2
- IRF6 | c.672T>G p.T224= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- IRX3 | c.903G>A p.E301= | Silent (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- MICALL2 | c.2568C>T p.D856= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs556137522; called by muse, mutect2, varscan2
- MYH15 | c.1836C>T p.L612= | Silent (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- NCDN | c.843A>C p.A281= | Silent (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- OR5H1 | c.309G>A p.S103= | Silent (SNP) | VAF 58/118 reads (49%) | catalogued as rs779446848, COSV63401624, COSV63401900; called by muse, mutect2, varscan2
- POLG | c.954C>G p.G318= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- RBM25 | c.744T>C p.F248= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- SCUBE2 | c.3033G>A p.S1011= (on ENST00000649792 / NM_001367977.2; = p.S954= on NM_020974.3) | Silent (SNP) | VAF 49/95 reads (52%) | catalogued as rs1291381213; called by muse, mutect2, varscan2
- ZNF572 | c.897C>T p.P299= | Silent (SNP) | VAF 85/169 reads (50%) | called by muse, mutect2, varscan2
- AAK1 | c.*17663C>A | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- AHDC1 | c.-155C>T | 5'UTR (SNP) | VAF 18/112 reads (16%) | catalogued as rs1053116200; called by muse, mutect2, varscan2
- AKAP13 | c.*4581C>T | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- ANKEF1 | c.*44G>T | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- ATP7B | c.*510G>A | 3'UTR (SNP) | VAF 39/39 reads (100%) | catalogued as rs886050304; called by muse, mutect2, varscan2
- C7 | c.*87G>A | 3'UTR (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- EIF4E3 | c.*502C>T | 3'UTR (SNP) | VAF 42/114 reads (37%) | called by muse, mutect2, varscan2
- EP400 | c.*813C>T | 3'UTR (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- F11 | c.*42A>T | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- GDAP1 | c.*1922T>A | 3'UTR (SNP) | VAF 9/69 reads (13%) | catalogued as COSV55186058; called by muse, mutect2, varscan2
- GPR85 | c.-455T>G | 5'UTR (SNP) | VAF 38/60 reads (63%) | called by muse, mutect2, varscan2
- KCNMA1 | c.*7828C>T | 3'UTR (SNP) | VAF 53/109 reads (49%) | catalogued as rs1453555203; called by muse, mutect2, varscan2
- KCTD7 | c.*2119G>T | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- KIR2DL3 | c.*66C>T | 3'UTR (SNP) | VAF 49/62 reads (79%) | catalogued as rs764983182; called by muse, mutect2, varscan2
- LANCL1 | chr2:210431349 T>G | 3'Flank (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ORC6 | c.*229C>T | 3'UTR (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- PER3 | c.*1296T>A | 3'UTR (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99277013; called by muse, mutect2
- PPHLN1 | chr12:42448260 T>C | 3'Flank (SNP) | VAF 26/49 reads (53%) | called by muse, mutect2, varscan2
- PPHLN1 | chr12:42448396 T>C | 3'Flank (SNP) | VAF 20/50 reads (40%) | called by muse, varscan2
- PPHLN1 | chr12:42448474 T>C | 3'Flank (SNP) | VAF 14/38 reads (37%) | catalogued as rs1411330699; called by muse, varscan2
- PPP2R5E | c.*389C>G | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- S1PR3 | c.-148+1193C>G | Intron (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- SGCB | c.*1635A>T | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, varscan2
- SHOX | c.-161G>T | 5'UTR (SNP) | VAF 45/151 reads (30%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.*3584C>G | 3'UTR (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.*3353G>A | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- SYNJ2BP | c.*4279_*4283del | 3'UTR (DEL) | VAF 4/41 reads (10%) | called by muse*, mutect2
- TMEM164 | c.*2757del | 3'UTR (DEL) | VAF 45/73 reads (62%) | called by mutect2, pindel, varscan2
- TMEM229B | c.*2680A>T | 3'UTR (SNP) | VAF 40/67 reads (60%) | called by muse, mutect2, varscan2
- USP31 | c.*755G>A | 3'UTR (SNP) | VAF 49/92 reads (53%) | called by muse, mutect2, varscan2
- ZNF780B | c.*5557T>G | 3'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
